CCDI case PBCDVY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/bc9ffc0e-f798-4f84-b7e7-298951d8a14a

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pleomorphic xanthoastrocytoma: ICD-O-3 morphology code: 9424/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 13.5 years (4,936 days).

Biospecimens (3 samples)
- Sample 0DPJSE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPJSW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPJTC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
